TARGET case TARGET-10-PARGYV — Acute Lymphoblastic Leukemia - Phase II (TARGET-ALL-P2)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Lymphoid Leukemias; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/dc572f4a-74ce-5728-ba8b-b871718c62c3

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 4 years; Vital status: Dead; Days to death: 704 days (1.9 years).

Diagnoses (1)
1. Acute lymphocytic leukemia: ICD-O-3 morphology code: 9835/3; ICD-10 code: C91.0; Tissue or organ of origin: Bone marrow; Classification of tumor: primary; Age at diagnosis: 4.2 years (1,541 days); Year of diagnosis: 2007; Days to last follow up: 704 days (1.9 years).
   Treatment given: Protocol identifier: AALL0232.

Follow-up (2 entries)
- Days to follow up: 412 days (1.1 years); Days to first event: 412 days (1.1 years); First event: Relapse.
- Days to follow up: 704 days (1.9 years); Progression or recurrence: Yes; Progression or recurrence anatomic site: Bone marrow; Year of follow up: 2009.

Molecular and laboratory tests (laboratory values grouped by visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- BCR–ABL1 fusion: Positive.
- ETV6–RUNX1 fusion (FISH): Negative.
- KMT2A rearrangement (FISH): Negative.
- TCF3–PBX1 translocation: Negative.
- Trisomy 10: Negative.
- Trisomy 4: Negative.
- Day 0: Leukocytes 334 ×10³/µL.
- Day 8: Bone Marrow blast count 25%; Minimal Residual Disease (Flow Cytometry) 2.07%.
- Day 15: Bone Marrow blast count 2%.
- Day 29: Bone Marrow blast count 1%; Minimal Residual Disease (Flow Cytometry) 0.048%.

Biospecimens (2 samples)
- Sample TARGET-10-PARGYV-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
- Sample TARGET-10-PARGYV-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the TARGET clinical supplement workbook TARGET_ALL_Blast_Data_20230727.xlsx, for sample TARGET-10-PARGYV-09A-01D:
- Blast %: Yes many

Additional fields from the TARGET clinical supplement workbook TARGET_ALL_ClinicalData_Phase_II_Validation_20230727.xlsx:
- Overall Survival Time in Days: 704
- WBC at Diagnosis: 333.5
- CNS Status at Diagnosis: CNS 2a
- Testicular Involvement: No
- MRD Day 8: 2.07
- MRD Day 8 Sensitivity: 0.01
- MRD Day 29: 0.048
- MRD Day 29 Sensitivity: 0.001
- Bone Marrow Site of Relapse: Yes
- CNS Site of Relapse: No
- Testes Site of Relapse: No
- Other Site of Relapse: No
- ETV6 RUNX1 Fusion Status: Negative
- TRISOMY 4 10 Status: Negative
- MLL Status: Negative
- TCF3 PBX1 Status: Negative
- BCR ABL1 Status: Positive
- BMA Blasts Day 8: 25
- BMA Blasts Day 15: 2
- BMA Blasts Day 29: 1
- Karyotype: 46,XY,add(2)(q31),der(5)t(2;5)(q31;q31),der(9)add(9)(p13)t(9;22)(q34;q11.2),der(22)t(9;22)(q34;q11.2)[10]/50,idem,+X,+6,+14,+21[6]/46,XY[4]
- Down Syndrome: No
- DNA Index: 1
- Alternate Therapy: Chemotherapy; Transplant
- Cell of Origin: B Cell ALL
